Surgical pathology report (de-identified scan), TCGA case TCGA-22-4601, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-4601-01A (Primary Tumor).

Surgical Pathology

TISSUE DESCRIPTION:

Tissue from right upper lobe lung (7.5 x 4 x 2.2 cm), right lower lobe lung (7 x 5 x 2.7 cm) and from right upper lobe hilar region (2 x 1.5 x 0.6 cm), superior (right lower paratracheal) and inferior (subcarinal, inferior pulmonary ligament) mediastinal lymph nodes

DIAGNOSIS:

Lung, right upper lobe, wedge excision: Invasive grade 3 (of 4) squamous cell carcinoma, forming a 0.7 x 0.5 x 0.5 cm nodule. The pleura and surgical margin are negative for neoplasm.

Lung, right lower lobe, wedge excision: Invasive grade 3 (of 4) squamous cell carcinoma forming a 2 x 2 x 1.2 cm mass with focal retraction and involvement of the pleura.

Soft tissue, right upper lobe hilar region, excision: Positive for invasive grade 3 (of 4) squamous cell carcinoma.

Lymph nodes, superior and inferior mediastinal, excision: Multiple superior (8 right lower paratracheal) and inferior (2 subcarinal, 2 inferior pulmonary ligament) mediastinal lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file cbb9470e-09b0-435f-9d23-5814a467333a (TCGA-22-4601.1DE412FD-DAF8-4125-9EFF-98E902A6C377.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).